Somatic mutation profile of tumor specimen TCGA-HC-7819-01A (aliquot TCGA-HC-7819-01A-11D-2114-08) from TCGA case TCGA-HC-7819, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.8 years (19,663 days).
Specimen TCGA-HC-7819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 504bf3fd-27e2-400e-9542-e4548a067aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7819-10A (Blood Derived Normal), aliquot TCGA-HC-7819-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e7e478-1a83-489e-8a10-bc3b74a80f59

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.7499C>T p.T2500M | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs200377748, COSV52148646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.1109T>C p.F370S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55610097; called by muse, mutect2, varscan2
- ANKAR | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55610119; called by muse, mutect2, varscan2
- GALNT10 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780564646, COSV51720121; called by muse, mutect2
- LENG8 | c.1929C>G p.C643W | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58726173; called by muse, mutect2
- LRFN5 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53245192; called by muse, mutect2, varscan2
- PCDHGA8 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV99535773; called by mutect2, varscan2
- PTPRA | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53778859; called by muse, mutect2, varscan2
- RNF43 | c.2260G>C p.G754R | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV68457109; called by muse, mutect2, varscan2
- SEMA3A | c.944A>C p.N315T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as COSV54863101; called by muse, mutect2, varscan2
- SERPINA6 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58583705; called by muse, mutect2, varscan2
- VPS50 | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52492999; called by muse, mutect2, varscan2
- LHX1 | c.245A>T p.K82I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- MAST2 | c.2492del p.V831Gfs*45 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.977_986del p.T326Ifs*27 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- AL353804.7 | chrX:73846669 A>T | 5'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
